Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A3SR, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A3SR-01A (Primary Tumor).

[page 1 of 5]
Gender: Male

DOB: }

Race: ..

Report Date:

Pathology Report:

Diagnostic Discrepancy		X
Reviewed Initials	RM	4/2/12

Surgical Pathology Report

ICD-O-3

carcinoma, urothelial, NOS
8120/3

FINAL PATHOLOGIC DIAGNOSIS

A. Left pelvic lymph nodes; dissection:

- Metastatic urothelial carcinoma in two of six lymph nodes (2/6).
- The largest tumor focus measures 1.0 cm.
- No extranodal extension present

Site:

path: bladder, NOS
C67.9

B. Ureter, left distal; excision:

- Segment of ureter with high-grade urothelial carcinoma involving periureteral fibroadipose tissue

CQCF: bladder, wall,
posterior
C67.4

49-12 RD

C. Lymph nodes, right pelvis; dissection:

- Metastatic urothelial carcinoma in one of ten lymph nodes (1/10)
- Tumor focus measures 0.2 cm.
- No extranodal extension present
- Separate fragments of high-grade urothelial carcinoma invading fibromuscular tissue.

D. Bladder, prostate, vas deferens; radical cystoprostatectomy:

- Urothelial carcinoma of the urinary bladder, high grade, transmurally invasive into perivesical and periprostacic soft tissue and bilateral seminal vesicles.
- Extensive urothelial carcinoma in situ (flat urothelial carcinoma) in the urinary bladder.
- Extensive lymphovascular invasion.
- Soft tissue margin of resection (posterior wall) positive for carcinoma
- Left ureter with high-grade urothelial carcinoma involving periureteral fibroadipose tissue.
- Margins of resection (prostatic urethra and right ureter), no tumor present.
- See pathologic parameters.

[page 2 of 5]
- Prostatic adenocarcinoma, Gleason score 6 (3+3).
- Tumor confined to the prostate gland.
- No extraprostatic extension present.
- Margins of resection, no tumor present.
- Seminal vesicles and vasa deferentia, no prostatic adenocarcinoma present.
- High-grade prostatic intraepithelial neoplasia (PIN).
- See pathologic parameters.

E. Periureteral tissue, left; excision:

- High grade urothelial carcinoma involving fibroadipose tissue.

F. Periureteral tissue, right; excision:

- High grade urothelial carcinoma involving fibroadipose tissue.

Urothelial Carcinoma Pathologic Parameters

1. Tumor type: Flat urothelial carcinoma
2. Grade of tumor: High grade
3. Depth of invasion: Seminal vesicles, perivesical and periprostatic soft tissue
4. Tumor distribution: Solitary (3.5 cm), involving dome, right lateral and posterior walls
5. Ureteral margins: Positive (left periureteral fibroadipose tissue)
6. Distal urethral margin: Negative
7. Soft tissue margin: Positive
8. Lymph nodes: Metastatic urothelial carcinoma in four of sixteen lymph nodes (4/16)
9. pTNM: pT4aN2MX

Radical Prostatectomy Pathologic Parameters

1. Gleason Score: 6 (3+3)
2. Perineural Invasion: Absent
3. Tumor Location: Peripheral zone - Left
4. Tumor Volume Estimate: Less than 1%
5. High-grade P.I.N.: Multifocal
6. Seminal Vesicles: Negative for prostatic adenocarcinoma
7. Extraprostatic extension: Absent
8. Peripheral Margin: Negative
9. Distal (apical) Margin: Negative

[page 3 of 5]
10. Proximal (basilar) Margin: Negative
11. Regional Lymph Nodes (right and left): Negative for prostatic adenocarcinoma
12. pTNM: pT2aN0MX

Effective this Checklist utilizes the edition TNM staging system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

xxx

[] M.D

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [] M.D.

Electronically Signed Out by [], M.D

Clinical History:

The patient is a ear old male with bladder cancer undergoing radical cystoprostatectomy.

Specimens Received:

- A: Lymph nodes left
- B: Distal left ureter
- C: Lymph node pelvic right
- D: Bladder, prostate, vas deferens
- E: Peri ureteral tissue
- F: Peri ureteral right

Gross Description:

Received are six containers, each labeled with the patient's name and medical record number.

A. Container A is further designated "1. Lymph nodes left." Received fresh and placed in formalin are multiple fragments of rubbery, yellow-tan fragments of fibrofatty tissue measuring 4.5 x 4 x 0.8 cm. A number of lymph node candidates are identified, the largest measuring 1.7 cm.

Block Summary:

- A1: one lymph node bisected
- A2: two lymph nodes
- A3: one lymph node
- A4: one lymph node
- A5: one lymph node bisected

[page 4 of 5]
B. Container B is further designated "2. Distal left ureter." Received fresh and placed in formalin is a triangle fragment of rubbery, tan-brown tissue measuring 1.2 x 2.1 x 0.4 cm. There is a stitch indicating the non-margin side. Opposite to the stitch is a luminal structure consistent with ureter. This non stitch end is shaved off thinly and submitted in cassette B1.

C. Container C is further designated "3. Lymph node pelvic right." Received fresh and placed in formalin is an aggregate of yellow-tan, lobulated, fibroadipose tissue measuring 6.5 x 4.5 x 1 cm. A number of lymph node candidates are identified, the largest measuring 1.2 cm.

Block Summary:

C1: one lymph node bisected

C2: four lymph nodes

C3: four lymph nodes

C4: one lymph node

C5: one lymph node bisected

D. Container D is further designated "4. Bladder, prostate, vas deferens." Received fresh and placed in formalin is a 386.3 grams cystoprostatectomy specimen that overall measures 16 x 10.5 x 4.5 cm. There is a bladder measuring 8 x 9 x 4 cm, right ureter measuring 3 x 0.4 cm, left ureter measuring 4.5 x 0.5 cm and prostate measuring 4.5 x 4.3 x 4 cm. The outer surface of the bladder is inked black. The left side of the prostate is also inked black and the right side of the prostate is inked blue. The specimen is opened by a Y shaped incision to reveal a right posterolateral eroded lesion near the dome measuring 3.5 x 1.8 cm. The lesion has foci of white-tan fibrotic tissue around it and extending from the areas of erythema. No other lesions or masses are identified within the bladder. There are two additional segments of vas deferens measuring 4.5 and 5.2 cm long. The specimen is serially sectioned from distal urethral margin to the bladder dome. The prostate contains discrete yellow-tan nodules with unremarkable parenchyma. The bladder is serially sectioned to reveal the lesion extending to a maximum depth of 1.4 cm that focally abuts the deep margin.

Block Summary:

D1: urethral margin

D2: left ureter margin

D3: right ureter margin

D4-D8: representative sections of right side of prostate

D9-D13: representative sections of left side of prostate

D14: right seminal vesicle and vas deferens

D15: left seminal vesicle and vas deferens

D16: section from bladder dome

D17: anterior wall

[page 5 of 5]
D18: posterior wall

D19: right wall

D20: left wall

D21: section from trigone

D22-D32: multiple sections of the lesion and surrounding erythematous tissue with D28-D30 sections from deepest invasion

E. Container E is further designated "5. Peri ureteral tissue." Received fresh and placed in formalin is a fragment of tan-brown to rubbery tissue measuring 1.8 x 0.6 x 0.2 cm submitted entirely in cassette E1.

F. Container F is further designated "6. Peri ureteral right." Received fresh and placed in formalin is a fragment of tan-brown, rubbery fragment of tissue covered by a scant amount of yellow-tan adipose tissue. The specimen measures 0.8 x 0.6 x 0.3 cm and submitted entirely in cassette F1.

xxx

[], M.D.

Source: NCI Genomic Data Commons file 19d5234e-07cc-4a37-a799-1f5129c80971 (TCGA-FD-A3SR.04E024F2-1D17-446A-868D-DCC2C2564103.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).